Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88T, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88T-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

~~Adenocarcinoma~~ NOS 8140/3
Site ^{CSCC} Distal third of esophagus C15.2
^{Path} Gastroesophageal junction C16.2
QW 11/12/13

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

Esophageal cancer. Operative Procedure: Transhiatal esophagectomy, cervical esophagogastric anastomosis, jejunostomy, feeding tube placement.

PROCEDURE:

VERIFIED BY:

1. "Distal esophagus, proximal stomach." Received in formalin in a large container is a previously opened 11.7 cm portion of distal esophagus and proximal stomach. Both margins are stapled. There is a small amount of adherent perigastric and periesophageal fat. The adventitia and serosa are unremarkable. The adventitia is inked green and the serosa is inked black. Arising over the esophagogastric junction is a 2.8 x 2.2 cm, raised, firm mass. Most of the multinodular, firm mass is in the gastric half of the EG

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

junction, yet some of the tumor involves the esophageal mucosa. The cut surface is gray-tan, homogenous and the maximum thickness is 0.7 cm. There is some penetration to the muscular wall, centrally. The remaining esophageal mucosa and gastric mucosa are unremarkable. Lymph node candidates retrieved from the fatty tissue are 1.4 cm in greatest dimension. The cut surface of the largest lymph node candidate is gray-white.

1A-E. EG junction tumor.

1F. Ten whole lymph node candidates.

1G. Bisected largest lymph node candidate.

2. "Cervical esophageal margin." Received in formalin in a small container is a 1.2 cm segment of esophagus that is stapled at one margin and opened at the opposing margin. The adventitia and mucosa are unremarkable.

2A. Cervical esophageal margin.

PROCEDURE:

VERIFIED BY:

ESOPHAGUS CARCINOMA
=====

LOCATION: Gastroesophageal junction (mostly below the junction).

SIZE: 2.8 cm.

TYPE OF CARCINOMA: Adenocarcinoma, cannot tell if arising in Barrett's mucosa or not

GRADE: Moderate.

DEPTH OF INVASION: Barely invading inner muscularis propria.

HAS IT BEEN TREATED PREOPERATIVE WITH CHEMO: No.

NUMBER OF POSITIVE LYMPH NODES/ TOTAL LYMPH NODES: 2/11.

METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: No.

pT2 N1

PROCEDURE:

VERIFIED BY:

1-2. Gastroesophageal junction, resection: Invasive, moderately-differentiated adenocarcinoma (2.8 cm), extending into inner muscularis propria. Margins

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

negative. Metastatic adenocarcinoma in two of eleven lymph nodes (2/11).
Please see TEMPLATE for details.

I, , the signing staff pathologist, have personally
examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Criteria	W 10/31/13	Yes	No

Source: NCI Genomic Data Commons file 2e45dbf4-c4ba-46f5-a723-4d9563ae43ed (TCGA-L5-A88T.DD3A7884-7F18-40FF-8A14-7C90658F43B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).